Somatic mutation profile of tumor specimen TCGA-GN-A4U7-06A (aliquot TCGA-GN-A4U7-06A-21D-A32N-08) from TCGA case TCGA-GN-A4U7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.4 years (20,606 days).
Specimen TCGA-GN-A4U7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bf88b02-f1e7-4b94-b5ce-e35835ceb9b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A4U7-10B (Blood Derived Normal), aliquot TCGA-GN-A4U7-10B-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de7052e0-3cf1-4ced-8271-f0e0df2d6ddb

The open-access MAF lists 305 somatic variants for this specimen: 190 protein-altering or splice-affecting, 113 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 113, Nonsense Mutation 10, Splice Region 2, Translation Start Site 2, Splice Site 2, In Frame Del 2, Frame Shift Ins 2, Frame Shift Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/174 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DYSF | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 30/71 reads (42%) | catalogued as rs1553521017, CM096563, COSV50390223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC097636.1 | c.432G>C p.Q144H | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV101469692; called by muse, mutect2, varscan2
- ACHE | c.1309A>G p.N437D | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99574548; called by muse, mutect2, varscan2
- ACOT11 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754487008, COSV59345955; called by muse, mutect2
- ADGRA3 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.183); catalogued as rs921364290, COSV100530299; called by muse, mutect2, varscan2
- ADGRV1 | c.8671G>A p.G2891S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV101316464; called by muse, mutect2, varscan2
- ADGRV1 | c.8672G>A p.G2891D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV67994332; called by muse, mutect2, varscan2
- ANK3 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1395573055, COSV99782218; called by muse, mutect2, varscan2
- AP1G2 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1325591645, COSV99846330; called by muse, mutect2, varscan2
- APOB | c.10472C>T p.S3491F | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV51951870; called by muse, mutect2, varscan2
- APOB | c.7045G>A p.E2349K | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.607); catalogued as COSV51923511; called by muse, mutect2, varscan2
- ARHGAP17 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.987); catalogued as COSV99254009; called by muse, mutect2, varscan2
- ARRDC5 | c.582G>A p.M194I (on ENST00000381781; = p.M180I on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs1449647760, COSV101108260; called by muse, mutect2, varscan2
- BCOR | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100654081; called by muse, mutect2, varscan2
- BICDL2 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs540888516, COSV101199477; called by muse, mutect2, varscan2
- BICDL2 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs746922361, COSV66370266; called by muse, mutect2, varscan2
- C10orf120 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 201/374 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs772291761, COSV100271761; called by muse, mutect2, varscan2
- C12orf40 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100210750; called by muse, mutect2, varscan2
- C1QL2 | c.845T>A p.F282Y | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99733348; called by muse, mutect2, varscan2
- C4A | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as rs540131398, COSV71179313; called by muse, mutect2, varscan2
- CACNA1F | c.5161G>A p.G1721S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100545361; called by muse, mutect2, varscan2
- CACNG5 | c.343T>C p.F115L | Missense Mutation (SNP) | VAF 103/212 reads (49%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.982); catalogued as COSV99400812; called by muse, mutect2, varscan2
- CAPZA3 | c.454A>T p.I152L | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV99856953; called by muse, mutect2, varscan2
- CASS4 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV64386800; called by muse, mutect2, varscan2
- CCDC15 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV100777061; called by muse, mutect2, varscan2
- CCDC189 | c.986A>T p.K329M | Missense Mutation (SNP) | VAF 183/428 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100079823; called by muse, mutect2, varscan2
- CD163 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.455); catalogued as COSV100776119; called by muse, mutect2, varscan2
- CD1B | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 130/423 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV100939295, COSV63805156; called by muse, mutect2, varscan2
- CFTR | c.3793G>T p.G1265* | Nonsense Mutation (SNP) | VAF 26/136 reads (19%) | catalogued as CM152277, COSV99139576, COSV99140651; called by muse, mutect2, varscan2
- CIAPIN1 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV101275927; called by muse, mutect2, varscan2
- CLDN6 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV58509216; called by muse, mutect2, varscan2
- CNGB1 | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99077072, COSV99209795; called by muse, mutect2, varscan2
- CNOT1 | c.433+1G>A p.X145_splice | Splice Site (SNP) | VAF 30/82 reads (37%) | catalogued as COSV100410006; called by muse, mutect2, varscan2
- CNTNAP2 | c.895T>C p.F299L | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100672073; called by muse, mutect2, varscan2
- CNTNAP5 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); catalogued as COSV101444193; called by muse, mutect2, varscan2
- COL11A2 | c.3926G>A p.G1309E (on ENST00000341947 / NM_080680.3; = p.G1202E on NM_080679.2) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1008221204, COSV59496878; called by muse, mutect2, varscan2
- COL11A2 | c.3925G>A p.G1309R (on ENST00000341947 / NM_080680.3; = p.G1202R on NM_080679.2) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779569420, COSV59495931; called by muse, mutect2, varscan2
- COL11A2 | c.1147G>A p.G383R (on ENST00000341947 / NM_080680.3; = p.G276R on NM_080679.2) | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs927171279, COSV100554497; called by muse, mutect2, varscan2
- COL12A1 | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs780955667, COSV100486460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL2A1 | c.4317G>A p.T1439= | Splice Region (SNP) | VAF 61/138 reads (44%) | catalogued as rs996256377, COSV100477420; called by muse, mutect2, varscan2
- CRHR2 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100530163; called by muse, mutect2, varscan2
- CSMD1 | c.3619C>T p.Q1207* (on ENST00000520002; = p.Q1206* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | catalogued as rs1164263475, COSV59355333; called by muse, mutect2, varscan2
- CUL9 | c.2498C>G p.A833G | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99336029; called by muse, mutect2, varscan2
- CYP3A5 | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV56118715; called by muse, mutect2, varscan2
- DGKH | c.2207C>T p.S736L | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs868257718, COSV54927833; called by muse, mutect2, varscan2
- DIDO1 | c.5198C>T p.T1733I | Missense Mutation (SNP) | VAF 173/277 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV99827059; called by muse, mutect2, varscan2
- DIDO1 | c.4387C>T p.P1463S | Missense Mutation (SNP) | VAF 196/301 reads (65%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1420946531, COSV56627752; called by muse, mutect2, varscan2
- DLG5 | c.3518C>T p.P1173L | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs759311731, COSV64946615; called by muse, mutect2, varscan2
- DLG5 | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100967855; called by muse, mutect2, varscan2
- DMWD | c.1825C>T p.L609F | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99353660; called by muse, mutect2, varscan2
- DNAH5 | c.779G>A p.W260* | Nonsense Mutation (SNP) | VAF 66/149 reads (44%) | catalogued as COSV54221661, COSV54250132; called by muse, mutect2, varscan2
- DOCK3 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as rs267599882, COSV99814878; called by muse, mutect2, varscan2
- DPEP3 | c.859A>C p.I287L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV99262870; called by muse, mutect2, varscan2
- DSC3 | c.2303G>A p.G768E | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs267605141, COSV64572654; called by muse, mutect2, varscan2
- DSCAM | c.4750G>A p.E1584K | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs758792903, COSV68021636; called by muse, mutect2, varscan2
- EFHC2 | c.1643T>G p.L548R | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV100638050; called by muse, mutect2
- EIF2AK3 | c.1400G>A p.G467D | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1416724116, COSV100304109; called by muse, mutect2, varscan2
- ENOX2 | c.1264C>T p.R422C (on ENST00000338144 / NM_001382520.1; = p.R393C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/170 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs148433684, COSV100584563; called by muse, mutect2, varscan2
- ENPP6 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.054); catalogued as COSV99699129; called by muse, mutect2, varscan2
- EPB41 | c.739G>A p.E247K (on ENST00000343067 / NM_001166005.2; = p.E38K on NM_004437.4) | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100549437; called by muse, mutect2, varscan2
- EPHX2 | c.1619A>T p.K540M | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV100994807; called by muse, mutect2, varscan2
- ERP29 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs755173279, COSV55673537; called by muse, mutect2, varscan2
- EXOSC10 | c.410A>T p.N137I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV100442884; called by muse, mutect2, varscan2
- FAM170A | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.264); catalogued as COSV58923993; called by muse, mutect2, varscan2
- FAT4 | c.3398G>A p.G1133E | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101272747; called by muse, mutect2, varscan2
- FOLH1 | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57058669, COSV99923896; called by muse, mutect2, varscan2
- G2E3 | c.885C>A p.F295L | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.086); catalogued as COSV99249877; called by muse, mutect2, varscan2
- GEMIN7 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV99541684; called by muse, mutect2, varscan2
- GKN1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 50/107 reads (47%) | catalogued as COSV100933616; called by muse, mutect2, varscan2
- GLIS3 | c.532G>C p.G178R | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100174802; called by muse, mutect2, varscan2
- GML | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV99638603; called by muse, mutect2, varscan2
- GRIK5 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs765080829, COSV53474503; called by muse, mutect2, varscan2
- HDAC9 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV67769639; called by muse, mutect2, varscan2
- HELZ2 | c.2651C>T p.P884L (on ENST00000467148 / NM_001037335.2; = p.P315L on NM_033405.3) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as rs1487691548, COSV100915696; called by muse, mutect2
- HELZ2 | c.2650C>T p.P884S (on ENST00000467148 / NM_001037335.2; = p.P315S on NM_033405.3) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs937075680, COSV100915698; called by muse, mutect2
- HIVEP1 | c.3572C>T p.S1191F | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV65098570; called by muse, mutect2, varscan2
- HTR6 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99230464; called by muse, mutect2, varscan2
- HYI | c.837A>T p.G279= (on ENST00000372434 / NM_001330526.2; = p.*248Cext*24 on NM_031207.6) | Splice Region (SNP) | VAF 83/199 reads (42%) | catalogued as COSV100981339; called by muse, mutect2, varscan2
- IGKV1-8 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 129/285 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1336077720; called by muse, varscan2
- ITGAD | c.692T>A p.I231N | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101210575; called by muse, mutect2, varscan2
- IZUMO1 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs755224650, COSV99711096; called by muse, mutect2, varscan2
- IZUMO2 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV53229372; called by muse, mutect2, varscan2
- KDM8 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs377614901; called by muse, mutect2, varscan2
- KIAA1210 | c.2603G>A p.S868N | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV101274383; called by muse, mutect2, varscan2
- KIAA1841 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99694217; called by muse, mutect2, varscan2
- KLHDC7A | c.1700G>A p.G567E | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1185788855, COSV101272847; called by muse, mutect2, varscan2
- KLRC3 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 38/79 reads (48%) | catalogued as COSV101122924; called by muse, mutect2, varscan2
- KSR2 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs769879825, COSV100351117; called by muse, mutect2, varscan2
- LBR | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 83/148 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99687682; called by muse, mutect2, varscan2
- LIPG | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99724732; called by muse, mutect2, varscan2
- LRFN2 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100599917; called by muse, mutect2, varscan2
- LRRC66 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV100603093; called by muse, mutect2, varscan2
- LUC7L2 | c.443A>T p.N148I | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV99693418; called by muse, mutect2, varscan2
- MAGEE2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV100973209; called by muse, mutect2, varscan2
- MAGT1 | c.637C>T p.L213F (on ENST00000618282 / NM_001367916.1; = p.L245F on NM_032121.5) | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV100800435; called by muse, mutect2, varscan2
- MAP1A | c.8174A>G p.N2725S | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375905188; called by muse, mutect2, varscan2
- MAP2K3 | c.568G>A p.D190N (on ENST00000342679 / NM_145109.3; = p.D161N on NM_002756.4) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100384461; called by muse, mutect2
- MAPK6 | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.059); catalogued as rs537289987, COSV99959420; called by muse, mutect2, varscan2
- MECOM | c.892G>A p.G298R (on ENST00000468789 / NM_001105078.4; = p.G486R on NM_004991.4) | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV99245315; called by muse, mutect2, varscan2
- MEFV | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as CM055425, COSV99561269; called by muse, mutect2, varscan2
- MGLL | c.853G>A p.E285K (on ENST00000398104 / NM_001003794.2; = p.E295K on NM_007283.6) | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99411466; called by muse, mutect2, varscan2
- MUC16 | c.23866G>A p.D7956N | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs372572295; called by muse, mutect2, varscan2
- MUC7 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 98/221 reads (44%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.03); catalogued as COSV59217349; called by muse, mutect2, varscan2
- MUSK | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 129/149 reads (87%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1485024100, COSV99505099; called by muse, mutect2, varscan2
- NCAN | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373196301; called by muse, mutect2, varscan2
- NCKAP1L | c.2455C>T p.P819S | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV99515650; called by muse, mutect2, varscan2
- NEK5 | c.1702A>T p.N568Y | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV100839300; called by muse, mutect2, varscan2
- NID2 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99356231, COSV99357221; called by muse, mutect2, varscan2
- NKX2-2 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 29/74 reads (39%) | catalogued as COSV101010624; called by muse, mutect2, varscan2
- NLRP13 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs770184597, COSV61624117; called by muse, mutect2, varscan2
- OCRL | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 166/396 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1393446335, COSV100843557; called by muse, mutect2, varscan2
- OR10G3 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV57811477; called by muse, mutect2, varscan2
- OR14C36 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV58601080; called by muse, mutect2, varscan2
- OR2A5 | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 78/271 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV101278846, COSV68738765; called by muse, mutect2
- OR6S1 | c.730T>G p.C244G | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100289520; called by muse, mutect2
- OR6T1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140103246, COSV58305755, COSV58309700; called by muse, mutect2, varscan2
- P4HA3 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 207/308 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV100525905; called by muse, mutect2, varscan2
- PAPPA2 | c.3623C>T p.S1208F | Missense Mutation (SNP) | VAF 89/151 reads (59%) | SIFT tolerated (0.64); PolyPhen benign (0.115); catalogued as rs267598192, COSV62792202; called by muse, mutect2, varscan2
- PCDH9 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.993); catalogued as COSV100123365; called by muse, mutect2, varscan2
- PCDH9 | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100123368, COSV60537184; called by muse, mutect2, varscan2
- PCLO | c.7009G>A p.E2337K | Missense Mutation (SNP) | VAF 113/210 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs370714669; called by muse, mutect2, varscan2
- PCLO | c.5342A>G p.E1781G | Missense Mutation (SNP) | VAF 135/205 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100437532; called by muse, mutect2, varscan2
- PDPR | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 81/547 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs772416517, COSV99848860; called by muse, mutect2, varscan2
- PKHD1L1 | c.1889G>A p.G630E | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV101007256, COSV65738689; called by muse, mutect2, varscan2
- PLCL2 | c.1202C>T p.S401F (on ENST00000615277 / NM_001144382.2; = p.S275F on NM_015184.5) | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV67621931; called by muse, mutect2, varscan2
- PNPLA1 | c.488dup p.T164Dfs*101 (on ENST00000394571 / NM_001374623.1; = p.T69Dfs*101 on NM_173676.2) | Frame Shift Ins (INS) | VAF 57/152 reads (38%) | catalogued as rs747341919; called by mutect2, pindel, varscan2
- PPFIA2 | c.3132C>A p.C1044* | Nonsense Mutation (SNP) | VAF 40/88 reads (45%) | catalogued as COSV100335147; called by muse, mutect2, varscan2
- PRMT7 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV59832921; called by muse, mutect2, varscan2
- PSD | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs983141949, COSV99193902; called by muse, mutect2, varscan2
- PSKH2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs762475706, COSV52611787; called by muse, mutect2, varscan2
- PTK2B | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs548687039, COSV100594432; called by muse, mutect2, varscan2
- PTPRT | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.303); catalogued as COSV100630320; called by muse, mutect2, varscan2
- R3HDM4 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100846444; called by muse, mutect2, varscan2
- RALB | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99732828; called by muse, mutect2, varscan2
- RASGEF1A | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV100988724; called by muse, mutect2, varscan2
- RBM41 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 132/276 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52563102; called by muse, mutect2, varscan2
- RGL1 | c.479G>A p.R160Q (on ENST00000360851 / NM_001297672.2; = p.R195Q on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 136/229 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs368885519; called by muse, mutect2, varscan2
- RGL1 | c.1783C>T p.H595Y (on ENST00000360851 / NM_001297672.2; = p.H630Y on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.61); catalogued as COSV100487675; called by muse, mutect2, varscan2
- RHBDD1 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100391487; called by muse, mutect2, varscan2
- RNF123 | c.1111-1G>A p.X371_splice | Splice Site (SNP) | VAF 53/135 reads (39%) | catalogued as COSV100571186; called by muse, mutect2, varscan2
- RNF123 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as rs1300610597, COSV100571187; called by muse, mutect2, varscan2
- RNF20 | c.2183T>C p.L728P | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101206580; called by muse, mutect2, varscan2
- RPTN | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 165/507 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100285757; called by muse, mutect2, varscan2
- RRP12 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs376656308; called by muse, mutect2, varscan2
- SATB1 | c.1653G>A p.M551I | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV100113444; called by muse, mutect2, varscan2
- SENP2 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.944); catalogued as COSV99958163; called by muse, mutect2, varscan2
- SLC16A14 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.698); catalogued as COSV54616999; called by muse, mutect2, varscan2
- SLC25A35 | c.494T>A p.L165* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV99873936; called by muse, mutect2, varscan2
- SLC34A1 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745939324, COSV53692886, COSV99499910; called by muse, mutect2, varscan2
- SLCO1B3 | c.2053G>A p.G685R | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV99682203; called by muse, mutect2, varscan2
- SLIT3 | c.4072G>A p.G1358S | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as rs551893384, COSV100269721; called by muse, mutect2, varscan2
- SPAG5 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs762761705, COSV100410851; called by muse, mutect2, varscan2
- SPTBN4 | c.7000G>A p.E2334K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100152057; called by muse, mutect2, varscan2
- SRP68 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.068); catalogued as COSV100326269; called by muse, mutect2, varscan2
- STAG1 | c.2492G>A p.S831N | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1292921906, COSV99366890; called by muse, mutect2, varscan2
- TACC2 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs780732675, COSV57761337; called by muse, mutect2, varscan2
- TBX15 | c.884G>A p.R295Q (on ENST00000369429 / NM_001330677.2; = p.R189Q on NM_152380.3) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376184438; called by muse, mutect2, varscan2
- THBS2 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as COSV100828073; called by muse, mutect2, varscan2
- THSD7B | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as rs866588841, COSV55651332; called by muse, mutect2, varscan2
- TIE1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as COSV100992181; called by muse, mutect2, varscan2
- TMEM130 | c.161T>A p.V54E | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100228989; called by muse, mutect2, varscan2
- TNPO2 | c.1313C>G p.P438R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100790412, COSV63509135; called by muse, mutect2, varscan2
- TOP3B | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as rs768895949, COSV100592790; called by muse, mutect2, varscan2
- TRPC5 | c.2189G>A p.R730K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV99462639; called by muse, mutect2, varscan2
- UBE3C | c.1439A>G p.Q480R | Missense Mutation (SNP) | VAF 64/291 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV100780081; called by muse, mutect2, varscan2
- UGT1A7 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 129/368 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100693193; called by muse, mutect2, varscan2
- UNC79 | c.2437G>A p.E813K (on ENST00000393151 / NM_001346218.2; = p.E636K on NM_020818.5) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV99829777; called by muse, mutect2, varscan2
- USF3 | c.3736C>T p.H1246Y | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100325779; called by muse, mutect2, varscan2
- WDR49 | c.965C>T p.P322L (on ENST00000308378 / NM_001366158.1; = p.P663L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.052); catalogued as COSV100393802; called by muse, mutect2, varscan2
- WWP1 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.972); catalogued as COSV99617174; called by muse, mutect2, varscan2
- XIRP1 | c.2264C>T p.P755L | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV100453960; called by muse, mutect2, varscan2
- ZIM3 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 105/224 reads (47%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.904); catalogued as rs771372793, COSV54139811; called by muse, mutect2, varscan2
- ZNF10 | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99939781; called by muse, mutect2, varscan2
- ZNF30 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100340753; called by muse, mutect2
- ZNF30 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs1053612980, COSV57854889; called by muse, mutect2
- ZNF41 | c.1265G>A p.R422K | Missense Mutation (SNP) | VAF 103/261 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100492278; called by muse, mutect2, varscan2
- ZNF468 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.17); catalogued as rs756642882, COSV99700807; called by muse, mutect2
- ZNF502 | c.1444C>T p.H482Y | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99939871; called by muse, mutect2, varscan2
- ZNF628 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as rs745632371, COSV99220278; called by muse, varscan2
- ZNF787 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as COSV99555766; called by muse, mutect2, varscan2
- ZNFX1 | c.1091G>A p.S364N | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as COSV100871009, COSV65577075; called by muse, mutect2, varscan2
- ADRA1B | c.706_714del p.N236_E238del | In Frame Del (DEL) | VAF 55/72 reads (76%) | called by mutect2, pindel, varscan2
- FCGBP | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 132/382 reads (35%) | called by muse, mutect2
- IGKV3D-20 | c.-1_2del | Translation Start Site (DEL) | VAF 63/183 reads (34%) | called by mutect2, pindel, varscan2
- METTL3 | c.1723_1726del p.S575Nfs*13 | Frame Shift Del (DEL) | VAF 29/87 reads (33%) | called by mutect2, pindel, varscan2
- MUC2 | c.1421C>T p.T474I | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.06); called by muse, mutect2, varscan2
- PRRC2B | c.4748_4752dup p.V1585Rfs*34 | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | called by mutect2, pindel
- XPOT | c.1606_1647del p.S536_S549del | In Frame Del (DEL) | VAF 54/252 reads (21%) | called by mutect2, pindel
- ADAMTS18 | c.1470G>A p.Q490= | Silent (SNP) | VAF 74/161 reads (46%) | catalogued as COSV51403577, COSV51422586; called by muse, mutect2, varscan2
- ADCY10 | c.3834C>T p.A1278= | Silent (SNP) | VAF 167/283 reads (59%) | catalogued as COSV100897079; called by muse, mutect2, varscan2
- ADRA2A | c.258C>T p.F86= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs375858769; called by muse, mutect2, varscan2
- APOBEC3G | c.630T>C p.P210= | Silent (SNP) | VAF 38/138 reads (28%) | catalogued as COSV101349112; called by muse, mutect2, varscan2
- ASIC4 | c.1050C>T p.C350= (on ENST00000347842 / NM_182847.3; = p.C369= on NM_018674.6) | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV99705294; called by muse, mutect2, varscan2
- BAG6 | c.798C>T p.S266= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as rs769519806, COSV99277595; called by muse, mutect2, varscan2
- CACNA1E | c.5775C>T p.P1925= | Silent (SNP) | VAF 121/422 reads (29%) | catalogued as rs759244871, COSV62392996; called by muse, mutect2, varscan2
- CASR | c.2739G>A p.R913= (on ENST00000490131; = p.R990= on NM_000388.4) | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs200174909, COSV56134662; called by muse, mutect2, varscan2
- CCDC189 | c.987G>A p.K329= | Silent (SNP) | VAF 186/431 reads (43%) | catalogued as COSV100079822; called by muse, mutect2, varscan2
- CCDC63 | c.525T>C p.N175= | Silent (SNP) | VAF 111/259 reads (43%) | catalogued as COSV100370604; called by muse, mutect2, varscan2
- CCNT1 | c.72C>T p.S24= | Silent (SNP) | VAF 110/289 reads (38%) | catalogued as COSV99980899; called by muse, mutect2, varscan2
- CDC20 | c.283C>T p.L95= | Silent (SNP) | VAF 60/130 reads (46%) | catalogued as rs1286882456, COSV100196644; called by muse, mutect2, varscan2
- CDCP1 | c.513G>T p.V171= | Silent (SNP) | VAF 79/198 reads (40%) | catalogued as COSV99944293; called by muse, mutect2, varscan2
- CHST4 | c.438C>T p.I146= | Silent (SNP) | VAF 55/107 reads (51%) | catalogued as COSV100632945; called by muse, mutect2, varscan2
- CHTF18 | c.498C>T p.P166= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as rs745492371, COSV99135981; called by muse, mutect2, varscan2
- CILP | c.34C>T p.L12= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as COSV99973900; called by muse, mutect2, varscan2
- CLDN6 | c.558C>T p.P186= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs756735225, COSV100172355; called by muse, mutect2, varscan2
- CSF1R | c.2073G>A p.Q691= | Silent (SNP) | VAF 71/84 reads (85%) | catalogued as COSV53836921, COSV99642985; called by muse, mutect2, varscan2
- CUL9 | c.2499C>T p.A833= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as rs770902357, COSV99336030; called by muse, mutect2, varscan2
- CXXC4 | c.1089C>T p.F363= | Silent (SNP) | VAF 64/157 reads (41%) | catalogued as COSV101182323; called by muse, mutect2, varscan2
- DEFA4 | c.135C>T p.S45= | Silent (SNP) | VAF 54/129 reads (42%) | catalogued as rs757777597, COSV99857770; called by muse, mutect2, varscan2
- DMWD | c.1824C>T p.V608= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs762606932, COSV99353663; called by muse, mutect2, varscan2
- DNAH9 | c.2067G>A p.T689= | Silent (SNP) | VAF 128/279 reads (46%) | catalogued as rs749709369, COSV52369181; called by muse, mutect2, varscan2
- DST | c.19473C>T p.F6491= (on ENST00000361203 / NM_001374722.1; = p.F4188= on NM_015548.5) | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99759753, COSV99759830; called by muse, mutect2, varscan2
- E2F1 | c.1215C>T p.P405= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV99865139; called by muse, mutect2
- EFNB3 | c.804C>T p.S268= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs1357865712, COSV99872968; called by muse, mutect2, varscan2
- EPHB2 | c.2046C>T p.V682= (on ENST00000400191 / NM_001309193.2; = p.V683= on NM_004442.7) | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as COSV101007380; called by muse, mutect2, varscan2
- FAM47C | c.1872G>A p.E624= | Silent (SNP) | VAF 117/262 reads (45%) | catalogued as COSV100792936; called by muse, varscan2
- FAT3 | c.8193G>A p.R2731= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV99967782; called by muse, mutect2, varscan2
- GALC | c.1230C>T p.T410= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV99730479; called by muse, mutect2, varscan2
- GC | c.1380T>A p.L460= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as rs781534238, COSV99910148; called by muse, mutect2, varscan2
- GCKR | c.411C>T p.L137= | Silent (SNP) | VAF 43/86 reads (50%) | catalogued as rs1359257810, COSV53022960; called by muse, mutect2, varscan2
- GET4 | c.618A>G p.L206= | Silent (SNP) | VAF 135/386 reads (35%) | catalogued as rs779652200, COSV99768881; called by muse, mutect2, varscan2
- GPC4 | c.93G>A p.S31= | Silent (SNP) | VAF 89/197 reads (45%) | catalogued as COSV100895603; called by muse, mutect2, varscan2
- GRIN2A | c.312G>A p.T104= | Silent (SNP) | VAF 78/167 reads (47%) | catalogued as COSV100410984, COSV58044855; called by muse, mutect2, varscan2
- GRIN2B | c.432C>T p.F144= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV101663183, COSV74207611; called by muse, mutect2, varscan2
- GTPBP2 | c.528C>T p.A176= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as rs1039491898, COSV100200151; called by muse, mutect2, varscan2
- HAUS5 | c.607C>T p.L203= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as COSV99178817; called by muse, mutect2, varscan2
- HSPB8 | c.174C>T p.S58= | Silent (SNP) | VAF 94/200 reads (47%) | catalogued as rs56046128, COSV56138265; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.126G>A p.K42= | Silent (SNP) | VAF 79/154 reads (51%) | catalogued as rs1184696473; called by muse, mutect2, varscan2
- IL17RD | c.174C>T p.F58= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99578068; called by muse, mutect2, varscan2
- ITGA3 | c.2136G>A p.Q712= | Silent (SNP) | VAF 59/136 reads (43%) | catalogued as COSV50307272, COSV50350248; called by muse, mutect2, varscan2
- ITGA6 | c.2181C>T p.P727= (on ENST00000442250; = p.P688= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/105 reads (53%) | catalogued as COSV51227267; called by muse, mutect2, varscan2
- KDM8 | c.555C>T p.P185= | Silent (SNP) | VAF 50/141 reads (35%) | catalogued as COSV99619979; called by muse, mutect2, varscan2
- KLHDC7A | c.1701G>A p.G567= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs762635147, COSV101272848; called by muse, mutect2, varscan2
- LRRC37A3 | c.3711C>T p.F1237= | Silent (SNP) | VAF 57/151 reads (38%) | catalogued as COSV100141491; called by muse, mutect2, varscan2
- MACROH2A2 | c.912G>A p.K304= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as rs1386156776, COSV100325821, COSV57161066; called by muse, mutect2, varscan2
- MAPK3 | c.555C>T p.F185= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs143182888; called by muse, mutect2, varscan2
- MFHAS1 | c.2391C>T p.L797= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as rs747107868, COSV99359910; called by muse, mutect2, varscan2
- MKI67 | c.9489G>A p.E3163= | Silent (SNP) | VAF 80/182 reads (44%) | catalogued as COSV100896653; called by muse, mutect2, varscan2
- MKS1 | c.708C>T p.I236= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as COSV100439765, COSV58304693; called by muse, mutect2, varscan2
- MRO | c.495G>A p.R165= | Silent (SNP) | VAF 102/209 reads (49%) | catalogued as rs866662881, COSV99839538; called by muse, mutect2, varscan2
- MSN | c.735C>T p.I245= | Silent (SNP) | VAF 66/164 reads (40%) | catalogued as COSV64303934; called by muse, mutect2, varscan2
- MSR1 | c.318G>A p.E106= | Silent (SNP) | VAF 82/196 reads (42%) | catalogued as COSV100028103; called by muse, mutect2, varscan2
- MUC16 | c.21048C>T p.L7016= | Silent (SNP) | VAF 122/278 reads (44%) | catalogued as rs570134052, COSV101201529, COSV67502717; called by muse, mutect2, varscan2
- MUCL3 | c.1425G>A p.R475= (on ENST00000304311; = p.R1351= on NM_080870.4) | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs267600947, COSV100424394, COSV58519571; called by muse, mutect2, varscan2
- MYO7A | c.3228G>A p.E1076= | Silent (SNP) | VAF 92/130 reads (71%) | catalogued as rs1555085540, COSV101289263; called by muse, mutect2, varscan2
- MYOCD | c.834C>A p.S278= | Silent (SNP) | VAF 53/106 reads (50%) | catalogued as COSV100591346; called by muse, mutect2, varscan2
- NANOS3 | c.258C>T p.P86= (on ENST00000397555; = p.P105= on NM_001098622.2) | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100188547; called by muse, mutect2, varscan2
- NBN | c.789T>C p.F263= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as COSV99620069; called by muse, mutect2, varscan2
- NFKBIB | c.474C>T p.P158= | Silent (SNP) | VAF 60/122 reads (49%) | catalogued as rs745419273, COSV58003907; called by muse, mutect2, varscan2
- NMUR2 | c.1023G>A p.V341= | Silent (SNP) | VAF 65/80 reads (81%) | catalogued as rs146688418; called by muse, mutect2, varscan2
- NRK | c.1476G>A p.Q492= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV54596589; called by muse, mutect2, varscan2
- OR2G3 | c.324C>T p.G108= | Silent (SNP) | VAF 274/450 reads (61%) | catalogued as COSV100180755, COSV60682377; called by muse, mutect2, varscan2
- OR5H6 | c.753A>G p.R251= (on ENST00000642105; = p.R235= on NM_001005479.2) | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV101051813; called by muse, mutect2, varscan2
- OR7G2 | c.249C>T p.F83= | Silent (SNP) | VAF 56/122 reads (46%) | catalogued as COSV100560602, COSV59687665; called by muse, mutect2, varscan2
- OR9A4 | c.210C>T p.I70= | Silent (SNP) | VAF 150/249 reads (60%) | catalogued as COSV101516546; called by muse, mutect2, varscan2
- ORC1 | c.2508C>T p.P836= | Silent (SNP) | VAF 68/165 reads (41%) | catalogued as COSV100856753; called by muse, mutect2, varscan2
- PBX1 | c.691C>T p.L231= | Silent (SNP) | VAF 53/79 reads (67%) | catalogued as rs1339461106, COSV100905272; called by muse, mutect2, varscan2
- PCDHA7 | c.1909C>T p.L637= | Silent (SNP) | VAF 71/94 reads (76%) | catalogued as COSV100971396, COSV100971778; called by muse, mutect2, varscan2
- PDE6D | c.150C>T p.P50= | Silent (SNP) | VAF 62/170 reads (36%) | catalogued as COSV99808113; called by muse, mutect2, varscan2
- PDZD2 | c.279C>T p.F93= | Silent (SNP) | VAF 83/181 reads (46%) | catalogued as rs146790239; called by muse, mutect2, varscan2
- PHF21A | c.807C>T p.F269= (on ENST00000418153 / NM_001101802.3; = p.F270= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV99139321; called by muse, mutect2, varscan2
- PIGM | c.1246C>T p.L416= | Silent (SNP) | VAF 161/287 reads (56%) | catalogued as COSV100928066; called by muse, mutect2, varscan2
- PLCD4 | c.493C>T p.L165= | Silent (SNP) | VAF 147/334 reads (44%) | catalogued as COSV101335827; called by muse, mutect2, varscan2
- PLCL2 | c.1203C>T p.S401= (on ENST00000615277 / NM_001144382.2; = p.S275= on NM_015184.5) | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as rs555516177, COSV101196977; called by muse, mutect2, varscan2
- PLIN1 | c.1122C>T p.S374= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as rs1387180277, COSV100261702; called by muse, mutect2, varscan2
- PLXNA4 | c.1869C>T p.I623= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV100326865; called by muse, mutect2, varscan2
- PMFBP1 | c.171G>A p.K57= | Silent (SNP) | VAF 61/143 reads (43%) | catalogued as COSV99401494; called by muse, mutect2, varscan2
- POLR1A | c.3693C>T p.F1231= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs1363482375, COSV99808377; called by muse, mutect2, varscan2
- PPP1R26 | c.303C>T p.L101= | Silent (SNP) | VAF 91/106 reads (86%) | catalogued as rs201939322, COSV63354683; called by muse, mutect2, varscan2
- PRODH2 | c.12G>A p.R4= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99995511; called by muse, varscan2
- PSMD12 | c.864C>T p.H288= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as rs1413801031, COSV100635427; called by muse, mutect2, varscan2
- R3HDM4 | c.534C>T p.A178= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs761137352, COSV100846429; called by muse, mutect2, varscan2
- RHBDD1 | c.45C>T p.L15= | Silent (SNP) | VAF 81/207 reads (39%) | catalogued as rs200858101, COSV100392207, COSV58125236; called by muse, mutect2, varscan2
- RNF34 | c.918C>T p.N306= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV100772155; called by muse, mutect2, varscan2
- SASH1 | c.3036C>T p.P1012= | Silent (SNP) | VAF 50/64 reads (78%) | catalogued as COSV66567317; called by muse, mutect2, varscan2
- SCPEP1 | c.564C>T p.T188= | Silent (SNP) | VAF 111/284 reads (39%) | catalogued as COSV99228001; called by muse, mutect2, varscan2
- SIGLEC10 | c.687C>G p.T229= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs573808895, COSV100219309, COSV100219428; called by muse, mutect2, varscan2
- SIGLEC14 | c.396G>A p.Q132= | Silent (SNP) | VAF 80/140 reads (57%) | catalogued as COSV99707893; called by muse, mutect2, varscan2
- SLC12A5 | c.1047C>T p.F349= (on ENST00000454036 / NM_001134771.2; = p.F326= on NM_020708.5) | Silent (SNP) | VAF 64/135 reads (47%) | catalogued as COSV99716787; called by muse, mutect2, varscan2
- SLC24A1 | c.1638C>T p.F546= | Silent (SNP) | VAF 94/188 reads (50%) | catalogued as COSV99978582; called by muse, mutect2, varscan2
- SLC34A2 | c.1620C>T p.I540= | Silent (SNP) | VAF 97/231 reads (42%) | catalogued as rs755925395, COSV101158455, COSV65941132; called by muse, mutect2, varscan2
- SLC44A2 | c.198C>T p.P66= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs146675623, COSV100213448; called by muse, mutect2, varscan2
- SLC9A2 | c.909C>T p.T303= | Silent (SNP) | VAF 75/167 reads (45%) | catalogued as COSV52136153; called by muse, mutect2, varscan2
- SP140 | c.2025G>A p.L675= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV100614061, COSV100614133; called by muse, mutect2, varscan2
- ST7 | c.1419C>T p.I473= (on ENST00000265437 / NM_021908.3; = p.I450= on NM_018412.4) | Silent (SNP) | VAF 179/313 reads (57%) | catalogued as COSV99622720; called by muse, mutect2, varscan2
- TACC2 | c.567C>T p.S189= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as COSV100553757; called by muse, mutect2, varscan2
- TENM4 | c.2946G>A p.Q982= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV99578999; called by muse, mutect2, varscan2
- TMC2 | c.1911G>A p.L637= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV62649992; called by muse, varscan2
- TOP3B | c.1137G>A p.R379= | Silent (SNP) | VAF 39/144 reads (27%) | catalogued as COSV100592788; called by muse, mutect2, varscan2
- TRMT11 | c.1326C>T p.F442= | Silent (SNP) | VAF 73/84 reads (87%) | catalogued as COSV100543304; called by muse, mutect2, varscan2
- TWIST1 | c.363C>T p.T121= | Silent (SNP) | VAF 45/78 reads (58%) | catalogued as COSV54250936, COSV99643084, COSV99643169; called by muse, mutect2, varscan2
- USP40 | c.3303C>T p.S1101= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99297142; called by muse, mutect2, varscan2
- VAV1 | c.756G>A p.K252= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV100409465; called by muse, mutect2, varscan2
- VPS51 | c.1635C>A p.L545= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV99659836; called by muse, mutect2, varscan2
- WEE2 | c.105G>A p.E35= | Silent (SNP) | VAF 115/365 reads (32%) | catalogued as rs777614689, COSV101285250; called by muse, mutect2, varscan2
- ZFPM2 | c.3144G>A p.L1048= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV65875173; called by muse, mutect2, varscan2
- ZNF226 | c.531C>T p.F177= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs1284269453, COSV100335247; called by muse, mutect2, varscan2
- ZNF226 | c.532C>T p.L178= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100335248; called by muse, mutect2, varscan2
- ZNF385B | c.126G>A p.E42= | Silent (SNP) | VAF 54/123 reads (44%) | catalogued as COSV101343193, COSV69802430; called by muse, mutect2, varscan2
- ZNF787 | c.939G>A p.E313= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99555768; called by muse, mutect2, varscan2
- ZNF81 | c.744T>C p.R248= | Silent (SNP) | VAF 58/120 reads (48%) | catalogued as COSV100096190; called by muse, mutect2, varscan2
- MIR323A | n.35C>T | RNA (SNP) | VAF 83/201 reads (41%) | catalogued as rs745701252; called by muse, mutect2, varscan2
- PGLYRP1 | chr19:46018964 G>A | 3'Flank (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
